Somatic mutation profile of tumor specimen TARGET-30-PAUBHV-01A (aliquot TARGET-30-PAUBHV-01A-01D) from TARGET case TARGET-30-PAUBHV, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 20.8 years (7,613 days).
Specimen TARGET-30-PAUBHV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b423483c-1177-4f99-a4b7-a6df051c1e08.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAUBHV-10A (Blood Derived Normal), aliquot TARGET-30-PAUBHV-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8a03a0dd-b087-41d4-a438-3f54e8984863

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Silent 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNAH2 | c.8668C>A p.L2890I | Missense Mutation (SNP) | VAF 65/134 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as COSV66730087; called by muse, mutect2, varscan2
- LIN28A | c.545C>A p.P182H | Missense Mutation (SNP) | VAF 67/79 reads (85%) | SIFT deleterious (0); PolyPhen benign (0.085); catalogued as COSV54263763; called by muse, mutect2, varscan2
- PARD3 | c.3751C>T p.Q1251* | Nonsense Mutation (SNP) | VAF 25/80 reads (31%) | catalogued as COSV61072509; called by muse, mutect2, varscan2
- LAMB2 | c.2209G>T p.A737S | Missense Mutation (SNP) | VAF 40/47 reads (85%) | SIFT tolerated (0.99); PolyPhen benign (0); called by muse, mutect2, varscan2
- FOXP2 | c.648C>A p.V216= | Silent (SNP) | VAF 41/137 reads (30%) | catalogued as COSV63496310; called by muse, mutect2, varscan2
